Somatic mutation profile of tumor specimen TARGET-10-PATWJU-09A (aliquot TARGET-10-PATWJU-09A-01D) from TARGET case TARGET-10-PATWJU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,127 days).
Specimen TARGET-10-PATWJU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41325f9f-ab47-451f-83dc-c07015fb4c7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWJU-10A (Blood Derived Normal), aliquot TARGET-10-PATWJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/041fa7cc-eb10-4fcf-868c-07b17fc55024

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 6, Silent 3, Frame Shift Ins 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRHL1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs200049769, COSV62910083; called by muse, mutect2, varscan2
- CATSPER4 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58793857; called by muse, mutect2
- DNAH3 | c.12037G>T p.D4013Y | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54535156; called by muse, mutect2, varscan2
- EPS8 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs201061069, COSV55533585; called by mutect2, varscan2
- GRIA2 | c.1646G>A p.C549Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52392529; called by muse, mutect2, varscan2
- MMP11 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53157208; called by muse, mutect2, varscan2
- NOTCH1 | c.7409_7410dup p.S2471Pfs*7 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as COSV53047176; called by mutect2, pindel, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NYAP2 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56010751; called by muse, mutect2, varscan2
- SNAI2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50078648, COSV50079793; called by muse, mutect2, varscan2
- DNM2 | c.2042_2043dup p.L682Tfs*3 (on ENST00000355667 / NM_001005360.3; = p.L678Tfs*3 on NM_004945.3) | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.1179G>A p.P393= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs565025247; called by muse, mutect2, varscan2
- PPP1R11 | c.336G>A p.Q112= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- WDFY4 | c.3282G>A p.T1094= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1025102712; called by muse, mutect2
- ATP6V0E2 | c.*222G>A | 3'UTR (SNP) | VAF 11/59 reads (19%) | catalogued as rs763116358, COSV70416726; called by muse, mutect2, varscan2
- CLK1 | c.391-19G>A | Intron (SNP) | VAF 16/43 reads (37%) | catalogued as rs980991822; called by muse, mutect2, varscan2
- EIF4B | c.533-176G>A | Intron (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- EPHX2 | c.735+22G>T | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- INTS10 | c.1883-73C>T | Intron (SNP) | VAF 16/61 reads (26%) | catalogued as rs1032978582; called by muse, mutect2, varscan2
- OR10D1P | n.282C>G | RNA (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- RPL38 | c.187+30G>A | Intron (SNP) | VAF 35/84 reads (42%) | catalogued as rs561484616; called by muse, mutect2, varscan2
- SLIT2 | c.179+980G>A | Intron (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
